Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD1-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

QW 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver Photo .

GROSS:

Specimen:

Liver: 9.0 x 7.5 x 5.5 cm, 203.0 gm (unfixed)

Operation: Segmentectomy

Lesion: A well-defined mass (6.3 x 5.0 x 3.5 cm)

Cut surface: Yellowish tan, and granular

Gross type

HCC: Multinodular confluent

Resection margin: Involved by tumor

Others:

Satellite nodule: no

Remaining parenchyma: Unremarkable

Portal vein invasion: No

Gross photo: Present

Blocks

T1-5 and TB, tumor and surrounding tissue x 6

RM, resection margin x 1

NB, remaining hepatic parenchyme x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation IV/IV

The major differentiation III/IV

Histologic type: Trabecular, pseudoglandular, compact

Cell type: Hepatic, clear

Fatty change: No

Cholangiocarcinoma: No

Combined hepatocellular and cholangiocarcinoma: No

Fibrous capsule formation: No

Septum formation: Yes

Surgical resection margin invasion: Yes

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma

T56000, P10, M81703

[page 2 of 2]
DIAGNOSIS:

Liver, segment 7, segmentectomy: Hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file 35727598-3d59-4966-b139-e1b32775766e (TCGA-DD-AAD1.D0035DF7-2E83-44E0-8FF1-C9A057E11AE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).